Somatic mutation profile of tumor specimen TCGA-HZ-7918-01A (aliquot TCGA-HZ-7918-01A-11D-2154-08) from TCGA case TCGA-HZ-7918, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.8 years (26,573 days).
Specimen TCGA-HZ-7918-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 462ff53d-8a58-4bc8-8a4b-c36f79f2c361.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-7918-10A (Blood Derived Normal), aliquot TCGA-HZ-7918-10A-01D-2154-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c51a6a4-2873-4716-ab23-248386ce2cec

The open-access MAF lists 133 somatic variants for this specimen: 101 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 30, Frame Shift Del 6, Splice Site 4, Nonsense Mutation 2, In Frame Del 1, Splice Region 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 37/680 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100641010; called by muse, mutect2
- ADPGK | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 90/508 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100295162; called by muse, mutect2, varscan2
- ARHGAP15 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 75/440 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as COSV99709061; called by muse, mutect2, varscan2
- ARID2 | c.3614G>C p.G1205A | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.23); catalogued as COSV100535600; called by muse, mutect2, varscan2
- BCAM | c.359A>C p.E120A | Missense Mutation (SNP) | VAF 13/241 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.367); catalogued as COSV99538530; called by muse, mutect2
- BCL11A | c.1690G>T p.D564Y (on ENST00000335712 / NM_001365609.1; = p.D598Y on NM_018014.4) | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV100185039; called by muse, mutect2, varscan2
- BRD4 | c.2682G>C p.L894F | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.795); catalogued as COSV99650075; called by muse, mutect2
- BSX | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545151; called by muse, mutect2
- C1QL3 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 16/376 reads (4%) | catalogued as COSV100126946; called by muse, mutect2
- C1orf162 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 71/427 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.17); catalogued as COSV100636169, COSV100636251; called by muse, mutect2, varscan2
- CC2D2A | c.3499G>T p.D1167Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101052685; called by muse, mutect2, varscan2
- CCDC6 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54060153, COSV99569235; called by muse, mutect2, varscan2
- CD58 | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65664504; called by muse, mutect2, varscan2
- CHD4 | c.3841-1G>T p.X1281_splice (on ENST00000357008 / NM_001363606.2; = p.X1294_splice on NM_001273.5) | Splice Site (SNP) | VAF 24/732 reads (3%) | catalogued as COSV100537531; called by muse, mutect2
- CHRNB2 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 74/729 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100872557; called by muse, mutect2, varscan2
- CLCN2 | c.47A>C p.Q16P | Missense Mutation (SNP) | VAF 48/386 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.054); catalogued as COSV99658293; called by muse, mutect2, varscan2
- COMMD8 | c.208T>G p.L70V | Missense Mutation (SNP) | VAF 63/499 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101055662; called by muse, mutect2, varscan2
- CRB1 | c.3154C>G p.Q1052E | Missense Mutation (SNP) | VAF 25/551 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.266); catalogued as COSV100957723; called by muse, mutect2
- CSPP1 | c.2100G>C p.M700I (on ENST00000676605; = p.M659I on NM_024790.6) | Missense Mutation (SNP) | VAF 118/1024 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99138100; called by muse, varscan2
- CTSF | c.1380G>A p.K460= | Splice Region (SNP) | VAF 15/138 reads (11%) | catalogued as rs930575227, COSV100074148; called by muse, mutect2, varscan2
- DMAP1 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 63/494 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100261591; called by muse, mutect2, varscan2
- DNAH9 | c.6466G>A p.G2156S | Missense Mutation (SNP) | VAF 44/397 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769107986, COSV99304660; called by muse, mutect2, varscan2
- DYM | c.1456A>T p.I486F | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV99492718; called by muse, mutect2, varscan2
- DYRK3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 20/616 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100895629; called by muse, mutect2
- EDAR | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99303203; called by muse, mutect2, varscan2
- EML4 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100580735; called by muse, varscan2
- EOMES | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 43/534 reads (8%) | catalogued as COSV99841778; called by muse, mutect2
- FAM180A | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100647236; called by muse, mutect2, varscan2
- FASN | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100147473; called by muse, mutect2, varscan2
- FBXW7 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1560865017, COSV99900130; called by muse, mutect2, varscan2
- FLT4 | c.677-2A>T p.X226_splice | Splice Site (SNP) | VAF 74/172 reads (43%) | catalogued as COSV99986217; called by muse, mutect2, varscan2
- FNBP1 | c.1550G>A p.S517N | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs751833858, COSV100852595, COSV100852859; called by muse, mutect2, varscan2
- FRYL | c.867G>C p.L289F | Missense Mutation (SNP) | VAF 55/411 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV51944695, COSV99976157; called by muse, mutect2, varscan2
- GATB | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 62/550 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99858812; called by muse, mutect2, varscan2
- GLI3 | c.1844C>G p.T615S | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV101229754; called by muse, mutect2, varscan2
- HBE1 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 118/680 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99496065; called by muse, mutect2, varscan2
- HMCES | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 90/566 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101077264; called by muse, mutect2, varscan2
- HMCN1 | c.3796G>C p.D1266H | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99625425; called by muse, mutect2, varscan2
- IGF2R | c.4465A>C p.S1489R | Missense Mutation (SNP) | VAF 30/692 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100807034; called by muse, mutect2
- ITGAE | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 198/1236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99560531; called by muse, mutect2, varscan2
- KAT6A | c.1171G>C p.D391H | Missense Mutation (SNP) | VAF 52/591 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV99704572; called by muse, mutect2
- KIF4B | c.2297A>C p.D766A | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV101469209; called by muse, mutect2, varscan2
- KMT2A | c.9167C>T p.P3056L | Missense Mutation (SNP) | VAF 31/866 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); catalogued as rs782800112, COSV100627560, COSV100628182; called by muse, mutect2
- KRT39 | c.1384T>C p.C462R | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100842171; called by muse, mutect2
- LARS2 | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99647501; called by muse, mutect2, varscan2
- LHB | c.15+2T>G p.X5_splice | Splice Site (SNP) | VAF 112/1139 reads (10%) | catalogued as COSV99668872; called by muse, varscan2
- LSM14A | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 97/749 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101471669; called by muse, mutect2, varscan2
- MCEMP1 | c.460A>G p.I154V | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100365315; called by muse, mutect2, varscan2
- MCM3 | c.472T>C p.C158R (on ENST00000229854 / NM_001366374.2; = p.C148R on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/570 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100008632; called by muse, mutect2, varscan2
- MROH6 | c.1696C>A p.L566M | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV101295795; called by muse, mutect2, varscan2
- MYO9B | c.4276G>C p.D1426H | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as COSV101261398; called by muse, mutect2
- NCAM1 | c.1715C>A p.T572N (on ENST00000316851 / NM_181351.5; = p.T562N on NM_000615.7) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100377139; called by muse, varscan2
- NEK10 | c.2045A>G p.E682G | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100411505; called by muse, mutect2
- NFKBIA | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV99394974; called by muse, mutect2
- NSUN5 | c.623T>A p.L208H | Missense Mutation (SNP) | VAF 40/533 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99392259; called by muse, mutect2
- NTMT1 | c.125T>A p.I42N | Missense Mutation (SNP) | VAF 115/733 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99475630; called by muse, mutect2, varscan2
- OPRL1 | c.523T>A p.W175R | Missense Mutation (SNP) | VAF 56/582 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100401981; called by muse, mutect2
- OR1J2 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 75/415 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.072); catalogued as COSV100093128; called by muse, mutect2, varscan2
- OR6Y1 | c.788C>A p.T263N | Missense Mutation (SNP) | VAF 102/737 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100225290; called by muse, mutect2, varscan2
- PIGO | c.269T>A p.V90E | Missense Mutation (SNP) | VAF 61/911 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs757353208, COSV99956475; called by muse, mutect2
- PITRM1 | c.2587G>T p.V863L | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99828395; called by muse, mutect2
- PLB1 | c.3580G>T p.D1194Y | Missense Mutation (SNP) | VAF 35/297 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV100577880; called by muse, mutect2, varscan2
- PPOX | c.946G>T p.V316L | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.299); catalogued as COSV99237192; called by muse, mutect2
- PRR22 | c.919T>A p.C307S | Missense Mutation (SNP) | VAF 42/350 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.021); catalogued as COSV100287984; called by muse, mutect2, varscan2
- PTDSS1 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 67/1017 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV100428513; called by muse, mutect2
- RAB3GAP2 | c.3649T>G p.L1217V | Missense Mutation (SNP) | VAF 84/469 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62787503; called by muse, mutect2, varscan2
- RFX3 | c.1178A>G p.D393G | Missense Mutation (SNP) | VAF 52/455 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as COSV100174696; called by muse, mutect2, varscan2
- RHOBTB2 | c.658C>G p.H220D | Missense Mutation (SNP) | VAF 87/673 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99310761; called by muse, mutect2, varscan2
- RNF38 | c.52C>G p.P18A | Missense Mutation (SNP) | VAF 80/600 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs746687265, COSV52397668, COSV99424829; called by muse, mutect2, varscan2
- SEPTIN4 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 64/660 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100400243; called by muse, mutect2
- SHARPIN | c.564G>C p.E188D | Missense Mutation (SNP) | VAF 45/469 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as COSV100010260; called by muse, mutect2, varscan2
- SLC2A13 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99786115; called by muse, mutect2, varscan2
- SLC3A2 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100101247; called by muse, mutect2, varscan2
- SLITRK3 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 68/605 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53851506, COSV99578723; called by muse, mutect2, varscan2
- SMARCA1 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1326501277, COSV100946409; called by muse, mutect2, varscan2
- SNX24 | c.84G>C p.M28I | Missense Mutation (SNP) | VAF 57/249 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV54451062; called by muse, mutect2, varscan2
- SPG7 | c.1354G>A p.D452N (on ENST00000268704; = p.D459N on NM_003119.4) | Missense Mutation (SNP) | VAF 78/546 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51951191, COSV99244682; called by muse, mutect2, varscan2
- TLNRD1 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV99146085; called by muse, mutect2
- TNXB | c.9544G>C p.E3182Q (on ENST00000647633; = p.E2935Q on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV100926005; called by muse, mutect2, varscan2
- TRIML1 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 165/972 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as COSV100205779, COSV60196705; called by muse, mutect2, varscan2
- TSNARE1 | c.146A>C p.E49A | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV100210006; called by muse, mutect2
- UBE2Q1 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 20/526 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV99427277; called by muse, mutect2
- VPS13B | c.1729C>G p.L577V | Missense Mutation (SNP) | VAF 146/494 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as COSV100661088, COSV62020246; called by muse, mutect2, varscan2
- ZHX1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 30/716 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99933530; called by muse, mutect2
- ZIC5 | c.1676A>T p.D559V | Missense Mutation (SNP) | VAF 146/553 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99940526; called by muse, mutect2, varscan2
- ZNF318 | c.5750G>T p.S1917I | Missense Mutation (SNP) | VAF 78/624 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as COSV100546013; called by muse, mutect2, varscan2
- ZNF514 | c.655C>A p.L219I | Missense Mutation (SNP) | VAF 31/853 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99727631; called by muse, mutect2
- ZNF556 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 90/559 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100298604; called by muse, mutect2, varscan2
- ZNF615 | c.569A>G p.Q190R | Missense Mutation (SNP) | VAF 125/1013 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV100943729; called by muse, mutect2, varscan2
- ZRANB3 | c.1669A>G p.T557A | Missense Mutation (SNP) | VAF 38/498 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as rs1232760397, COSV99922858; called by muse, mutect2
- ZSWIM5 | c.2488C>A p.Q830K | Missense Mutation (SNP) | VAF 171/1235 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV100655399; called by muse, varscan2
- CDCP2 | c.1026del p.V344* | Frame Shift Del (DEL) | VAF 34/274 reads (12%) | called by pindel, varscan2
- CHD6 | c.3035G>C p.R1012T | Missense Mutation (SNP) | VAF 18/702 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2
- COCH | c.1418_1425del p.A473Vfs*4 (on ENST00000216361 / NM_001347720.1; = p.A408Vfs*4 on NM_004086.3) | Frame Shift Del (DEL) | VAF 40/445 reads (9%) | called by mutect2, pindel
- ELMO3 | c.1338G>T p.E446D (on ENST00000652269; = p.E393D on NM_024712.5) | Missense Mutation (SNP) | VAF 35/1450 reads (2%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2
- KLHL38 | c.375_402del p.Y126Tfs*5 | Frame Shift Del (DEL) | VAF 37/328 reads (11%) | called by mutect2, pindel
- MRPL48 | c.321_331del p.Y109Pfs*8 | Frame Shift Del (DEL) | VAF 42/275 reads (15%) | called by mutect2, pindel, varscan2
- OTUD7B | c.1238+2_1238+10del p.X413_splice | Splice Site (DEL) | VAF 44/384 reads (11%) | called by mutect2, pindel
- RNF135 | c.1066_1076del p.Q356Mfs*24 | Frame Shift Del (DEL) | VAF 38/334 reads (11%) | called by mutect2, pindel, varscan2
- SSH3 | c.1079_1097del p.N360Tfs*64 | Frame Shift Del (DEL) | VAF 46/480 reads (10%) | called by mutect2, pindel
- ZNF503 | c.1854_1859del p.V619_P620del | In Frame Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- ABCB1 | c.1629T>C p.R543= | Silent (SNP) | VAF 78/486 reads (16%) | catalogued as rs752735819, COSV99712389; called by muse, varscan2
- ADAMTS10 | c.1089G>T p.L363= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV99546574; called by muse, mutect2, varscan2
- CACNA1C | c.4041G>C p.R1347= | Silent (SNP) | VAF 40/253 reads (16%) | catalogued as COSV100216492; called by muse, mutect2, varscan2
- CELA3A | c.177C>T p.G59= | Silent (SNP) | VAF 61/686 reads (9%) | catalogued as rs774023252; called by muse, mutect2
- DLG5 | c.2076C>T p.I692= | Silent (SNP) | VAF 26/865 reads (3%) | catalogued as COSV100967316; called by muse, mutect2
- DPP8 | c.535C>T p.L179= (on ENST00000341861 / NM_001320875.2; = p.L163= on NM_017743.6) | Silent (SNP) | VAF 106/913 reads (12%) | catalogued as COSV100202163, COSV55678448; called by muse, mutect2, varscan2
- HRNR | c.7008T>A p.G2336= | Silent (SNP) | VAF 145/4556 reads (3%) | catalogued as COSV100913439; called by muse, mutect2
- KLHL11 | c.2016C>T p.Y672= | Silent (SNP) | VAF 105/728 reads (14%) | catalogued as COSV100044229; called by muse, mutect2, varscan2
- LRRC6 | c.1191T>A p.T397= | Silent (SNP) | VAF 35/421 reads (8%) | catalogued as COSV99137790; called by muse, mutect2
- LSS | c.1935C>A p.A645= | Silent (SNP) | VAF 41/203 reads (20%) | catalogued as COSV100710830; called by muse, mutect2, varscan2
- MYO3B | c.3009G>C p.V1003= | Silent (SNP) | VAF 64/462 reads (14%) | catalogued as COSV100509422; called by muse, varscan2
- NLRP5 | c.3258C>T p.C1086= | Silent (SNP) | VAF 53/402 reads (13%) | catalogued as rs764666206, COSV66763493; called by muse, mutect2, varscan2
- NOS2 | c.798C>A p.R266= | Silent (SNP) | VAF 15/446 reads (3%) | called by muse, mutect2
- NSUN5 | c.624C>T p.L208= | Silent (SNP) | VAF 40/538 reads (7%) | catalogued as COSV99392257; called by muse, varscan2
- OCRL | c.948G>A p.L316= | Silent (SNP) | VAF 89/442 reads (20%) | catalogued as COSV100843356; called by muse, mutect2, varscan2
- OR10K2 | c.534C>T p.F178= | Silent (SNP) | VAF 97/603 reads (16%) | catalogued as COSV59222037; called by muse, mutect2, varscan2
- PDE8B | c.261G>A p.A87= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs746859495, COSV99366309; called by muse, varscan2
- PLK4 | c.303A>G p.L101= | Silent (SNP) | VAF 95/384 reads (25%) | catalogued as rs893628118, COSV99584476; called by muse, mutect2, varscan2
- PRKDC | c.8182C>T p.L2728= | Silent (SNP) | VAF 158/1013 reads (16%) | catalogued as COSV100038943; called by muse, mutect2, varscan2
- SCAF8 | c.672C>T p.A224= | Silent (SNP) | VAF 80/382 reads (21%) | catalogued as COSV100913973; called by muse, mutect2, varscan2
- SLC17A9 | c.471C>T p.S157= | Silent (SNP) | VAF 23/204 reads (11%) | catalogued as COSV100947745; called by muse, mutect2
- SLC25A13 | c.874C>A p.R292= | Silent (SNP) | VAF 35/206 reads (17%) | catalogued as COSV55709201, COSV99673175; called by muse, mutect2, varscan2
- SPATA2L | c.891G>A p.E297= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs1180045609, COSV57046085; called by muse, mutect2, varscan2
- TAF1L | c.727T>C p.L243= | Silent (SNP) | VAF 48/601 reads (8%) | catalogued as COSV99644245; called by muse, mutect2
- TAMM41 | c.762C>G p.T254= | Silent (SNP) | VAF 43/556 reads (8%) | catalogued as COSV99808712; called by muse, mutect2
- TAOK1 | c.2196C>T p.I732= | Silent (SNP) | VAF 28/237 reads (12%) | catalogued as rs978854156, COSV99913654; called by muse, mutect2, varscan2
- TBX18 | c.918C>T p.V306= | Silent (SNP) | VAF 33/240 reads (14%) | catalogued as COSV100858457, COSV63736423; called by muse, mutect2, varscan2
- TIMP1 | c.588G>C p.L196= | Silent (SNP) | VAF 13/251 reads (5%) | catalogued as COSV99512131; called by muse, mutect2
- TRAV16 | c.90C>T p.L30= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- TRMT61A | c.264C>T p.Y88= | Silent (SNP) | VAF 109/618 reads (18%) | catalogued as COSV100149329; called by muse, mutect2, varscan2
- ANKRD13D | c.*946C>T | 3'UTR (SNP) | VAF 32/369 reads (9%) | catalogued as rs1195423806, COSV100354435; called by muse, mutect2
- KLK8 | c.71-80C>T | Intron (SNP) | VAF 42/496 reads (8%) | catalogued as COSV99143902; called by muse, mutect2
